Surgical pathology report (de-identified scan), TCGA case TCGA-06-0201, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0201-01A (Primary Tumor).

TCGA-06-0201

PATHOLOGICAL DIAGNOSIS:

1. BRAIN, SITE NOT SPECIFIED, BIOPSY: NECROTIC TISSUE, NON-DIAGNOSTIC.
2. BRAIN, SITE NOT SPECIFIED, BIOPSY: GLIOBLASTOMA MULTIFORME.
- SEE DESCRIPTIONS AND COMMENT.

Operation/Specimen: Brain.

Clinical History and Pre-Op Dx: A [REDACTED] with a lesion in the right parietal lobe. The patient is currently lethargic and has an extensive mass lesion.

GROSS PATHOLOGY: 1. Received in fresh state for intraoperative consultation and labeled with the patient's name, the specimen consists of several small fragments of friable hemorrhagic soft tissue measuring 2 x 2 x 0.2 cm in aggregate. Smears obtained and remaining tissue submitted in toto in cassette 1.

INTRAOPERATIVE CONSULTATION: Brain, site not specified: Necrotic tissue, non-diagnostic.

2. Received in fresh state for intraoperative consultation and labeled with the patient's name as "tumor second piece", the specimen consists of three small fragments of friable, hemorrhagic tissue measuring 0.9 x 0.9 x 0.2 cm. Smears obtained and remaining tissue submitted in toto in cassette 2.

INTRAOPERATIVE CONSULTATION: Brain, site not specified: Glioma, high grade.

MICROSCOPIC: 1. The sections contain portions of necrotic tissue in which there are some vessels with necrotic walls and thrombosis. No viable tissue is present.

2. The sections contain portions of necrotic tissue similar to those described in specimen 1, and portions of a neoplastic glial proliferation with features of anaplasia, namely nuclear pleomorphism and hyperchromasia, mitotic figures, endothelial vascular proliferation and areas of tumor necrosis.

Comment: Specimen 1 is non-diagnostic and consists of necrotic tissue. In specimen 2, there is a malignant glioma with extensive areas of necrosis, namely a glioblastoma multiforme. [REDACTED]

Source: NCI Genomic Data Commons file 596d7187-f5bb-4292-8c11-c5565a8163a2 (TCGA-06-0201.96324E62-340C-4865-9729-E9A547DF2DF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).